Surgical pathology report (de-identified scan), TCGA case TCGA-NA-A4QW, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Duke University, specimen TCGA-NA-A4QW-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

Surg Path

CLINICAL HISTORY:

Malignant neoplastic uterus

GROSS EXAMINATION:

A. "Uterus, cervix, bilateral tubes and ovaries", received fresh and placed in formalin is a 134 gram (10.8 x 6 x 1.3 cm) hysterectomy specimen. The specimen is opened to reveal a 6 x 5 x 3.8 cm pedunculated soft yellow-tan mass primarily located within the posterior endometrial cavity (4.5 x 3.3 cm). The mass is located 4 cm from the internal os (0.7 cm) and does not grossly appear to invade the lower uterine segment endocervical canal. The mass is sectioned to demonstrate a fleshy, focally lobulated white-tan cut surface with focal areas of cystic change up to 0.7 cm. The mass does not appear to invade the underlying myometrium (1.3 cm). The remainder of the endometrium is grossly unremarkable (0.1 cm). Three intramural nodules up to 1.7 cm in greatest dimension are identified. These nodules are well circumscribed, whorled, white-tan with a bulging cut surface. No areas of hemorrhage and necrosis are identified in these nodules.

BLOCK SUMMARY:

- A1- anterior cervix.
- A2- anterior lower uterine segment/upper endocervical canal.
- A3- posterior cervix.
- A4- posterior lower uterine segment/upper endocervical canal.
- A5- anterior endomyometrial insertion of mass.
- A6- posterior endomyometrial insertion of mass.
- A7-A9- representative mass.
- A10- uninvolved anterior endomyometrium.
- A11- uninvolved posterior endomyometrium with nodules.
- A12- representative nodules.
- A15-19- more tumor/myometrium junction

ICD-O-3
Mixed Mullerian Tumor 8950/3
Site: Corpus Uteri C54.9
Copied AUS 1/6/13

The right adnexa is composed of a 6.2 cm long x 0.3 cm in diameter fimbriated fallopian tube and attached mesentery and a 2.5 x 1.4 x 0.7 cm yellow bosselated ovary. The cut surface of the ovary is grossly unremarkable. Representative sections of right adnexa are submitted in block A13.

The left adnexa is composed of a 5 cm long x 0.4 cm in diameter fimbriated fallopian tube and attached mesentery and a 2.3 x 1.1 x 0.9 cm yellow bosselated ovary. The cut surface of the ovary is grossly unremarkable. Representative sections of left adnexa are submitted in block A14.

B. "Left pelvic nodes". Received fresh and placed in formalin is a 6.4 x 5.1 x 1.5 cm aggregate of yellow-tan fibroadipose tissue which is dissected for apparent lymph node candidates. Twelve lymph node candidates are identified and submitted as follows:

BLOCK SUMMARY:

- B1- six lymph node candidates.
- B2- one lymph node candidate, sectioned.
- B3- one lymph node candidate.
- B4- one lymph node candidate, bisected.
- B5-B6- one lymph node candidate, bisected.
- B7-B8- one lymph node candidate, sectioned.
- B9-B10- one lymph node candidate, sectioned.

The lymph node candidate range in greatest dimension from 0.6 cm to 3.5 cm.

[REDACTED]

[page 2 of 3]
C. "Right pelvic node", received fresh and placed in formalin is a 5.1 x 4.6 x 2.5 cm aggregate of yellow-tan fibroadipose tissue which is dissected for apparent lymph node candidates. Nine lymph node candidates are identified and range in size 0.7 cm to 4.5 cm in greatest dimension. The lymph node candidates are submitted as block C1.

C1- four lymph node candidates.

C2- two lymph node candidates.

C3-C5- one lymph node candidate, sectioned.

C6-C8- one lymph node candidate, sectioned.

C9-C13- one lymph node candidate, sectioned.

D. "Para-aortic", received fresh and placed in formalin is a 4 x 1.7 x 0.5 cm fragment of yellow-tan fibroadipose tissue which is dissected for apparent lymph node candidates. Two lymph node candidates are identified and measures 2.5 cm and 1 cm in greatest dimension. One lymph node candidate is submitted in block D1. One lymph node candidate is submitted in block D2 (bisected)

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: hysterectomy and salpingoophorectomy, with node dissection

PATHOLOGIC STAGE (AJCC 6th Edition): pT2a pN0 pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "UTERUS, CERVIX, BILATERAL TUBES AND OVARIES" (RADICAL HYSTERECTOMY):

UTERUS: 134 GRAMS

ENDOMETRIUM:

TUMOR SITE: CORPUS FUNDUS

HISTOLOGIC TYPE: MALIGNANT MIXED MULLERIAN TUMOR

FIGO GRADE: 3

TUMOR SIZE: 6 X 5 X 3.8 CM.

MAXIMUM DEPTH OF MYOMETRIAL INVASION: 0.0 CM, IN A 1.3 THICK WALL.

LYMPHATIC/VASCULAR INVASION: NEGATIVE

ADJACENT NON-NEOPLASTIC ENDOMETRIUM: BENIGN ENDOMETRIAL POLYP AND ATROPHIC ENDOMETRIUM

REMAINING MYOMETRIUM: LEIOMYOMATA AND ADENOMYOSIS.

CERVIX: ENDOCERVIX POSITIVE FOR GLANDULAR INVOLVEMENT BY TUMOR,

NEGATIVE FOR STROMAL INVASION

SEROSA: NEGATIVE FOR MALIGNANCY.

SPECIMEN MARGINS: NOT INVOLVED

OVARIES AND FALLOPIAN TUBES, BILATERAL: NO PATHOLOGIC DIAGNOSIS.

B. "LEFT PELVIC NODE" (LYMPH NODE DISSECTION):

TEN LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/10).

[page 3 of 3]
C. "RIGHT PELVIC NODE" (LYMPH NODE BIOPSY):

NINE LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/9).

D. "PARA-AORTIC NODE" (LYMPH NODE BIOPSY):

TWO LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/2).

COMMENT: The uterine tumor is composed of a proliferation of malignant appearing epithelial elements, mainly glandular in appearance, along with an extensive malignant appearing stromal component with heterologous elements including rhabdoid cells. This is interpreted to represent malignant mixed Mullarian tumor. Multiple sections do not demonstrate any definite muscular or vascular invasion.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

ADDENDUM 1:

reports that part D of this case is actually "para-aortic lymph nodes" and not "right pelvic nodes", as is stated on the specimen container and requisition. This report is corrected on to reflect the correct identification of part "D".

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 79fd6899-abe2-47f4-b51d-d5193259ebd6 (TCGA-NA-A4QW.BC92A01F-F97A-4046-A850-44CD79BEBD65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).